Somatic mutation profile of tumor specimen 0DDEQD from CCDI case PBBNMG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 17.9 years (6,524 days).
Specimen 0DDEQD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5abdf49-fa3a-4a23-adaa-d0a310f8464e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDEQA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72939b4c-0bcd-4111-b8fb-f1054d801d47

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 208/504 reads (41%) | catalogued as rs886037667, COSV58619506; ClinVar: pathogenic; called by muse, varscan2
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, varscan2
- IMPG1 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 202/482 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.153); catalogued as rs1399300141, COSV64054078, COSV64057361; called by muse, varscan2
- CRNN | c.658G>C p.A220P | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, varscan2
- NR1D2 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 141/320 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- ADIPOQ | c.174A>G p.R58= | Silent (SNP) | VAF 148/376 reads (39%) | called by muse, varscan2
- LRRTM4 | c.1032C>T p.H344= | Silent (SNP) | VAF 77/240 reads (32%) | called by muse, varscan2
- NAXD | c.1026G>A p.P342= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as rs767874491; called by muse, varscan2
- RARS1 | c.579+80T>C | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 6/29 reads (21%) | called by muse, varscan2
